Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8X3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8X3-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate C61.9
W 8/28/14

FINAL PATHOLOGIC DIAGNOSIS

- A. Urethra, anterior margin, biopsy: Fibrofatty tissue, no tumor seen.
- B. Prostate and seminal vesicles, prostatectomy:
1. Prostatic adenocarcinoma, Gleason grade 3+5=8, bilateral involvement, with extraprostatic extension, tumor at cauterized margin; see comment.
2. Seminal vesicles with no carcinoma.
- C. Left pelvic lymph nodes, dissection: No carcinoma in seven lymph nodes (0/7).
- D. Right pelvic lymph nodes, dissection: No carcinoma in 11 lymph nodes (0/11).

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:**
- Left apex: Slide B1.
- Left mid gland: Slides B5, B7, B9, B13.
- Right apex: Slides B2, B4.
- Right mid gland: Slides B6, B8, B12, B14.
- Right base: Slide B16.
- **Estimated volume of tumor:** 2.2 cubic cm.
- **Gleason score:** 3+5=8.
- **Estimated volume > Gleason pattern 3:** 0.3 cubic cm.
- **Involvement of capsule:** Tumor invades capsule: Left mid gland (slides B7, B9, B13), right mid gland (slides B8, B12).
- **Extraprostatic extension:** Present.
- **Margin status for tumor:** Positive; right mid gland (slides B8, B12), left mid gland (slide B9).
- **Margin status for benign glands:** No benign glands present at inked excision margins.
- **Involvement of seminal vesicle:** None.

[page 2 of 3]
- **Perineural infiltration:** Present.
- **Prostatic intraepithelial neoplasia (PIN):** None.
- **AJCC/UICC stage:** pT3aR1N0MX.

Dr. _____ has reviewed selected slides and concurs with the findings.

Specimen(s) Received

A: Anterior urethral margin (FS)
B: Prostate and seminal vesicles (fresh)
C: Left pelvic lymph nodes
D: Right pelvic lymph nodes

Intraoperative Diagnosis

FS1 (A) Anterior urethral margin, biopsy: Smooth muscle, skeletal muscle, fibroadipose tissue and nerve. No epithelium, no tumor. (Dr. _____)

Clinical History

The patient is a _____-year-old man with history of prostate cancer, Gleason grade 3+3.

Gross Description

The specimen is received fresh and in formalin in four parts, each labeled with the patient's name and unit number. Parts A and B are received fresh, and Parts C and D are received in formalin.

Part A is additionally labeled "anterior urethral margin." It consists of two soft, irregular pieces of red-black tissue measuring 1.4 x 1 x 0.3 cm in aggregate. The specimen is submitted for frozen section diagnosis #1, and the frozen section remnant is submitted in cassette A1.

Part B is additionally labeled "prostate + seminal vesicles." It consists of a prostate gland with attached seminal vesicles weighing 36 gm and measuring 3.5 cm anterior-posterior, 5 cm apex-base, and 4 cm medial-lateral. The left seminal vesicle bundle measures 4 x 0.75 x 0.5 cm; the right measures 3.75 x 0.75 x 0.5 cm. The posterior is inked black, left anterior blue, right anterior green, the apex and base margins removed and the prostate serially sectioned from apex to base across the urethra into six serial slices revealing prominent nodular hyperplasia around the urethra and firm, pink-tan peripheral zone throughout. Tissue is removed from the left and right slices 2, 3, and 4 and frozen for research purposes. The remaining tissue is then entirely submitted as follows:

Apex

Cassette B1: Left.
Cassette B2: Right.

Slice 1

Cassette B3: Left.
Cassette B4: Right.

Slice 2

Cassette B5: Left.
Cassette B6: Right.

Slice 3

Cassette B7: Left.
Cassette B8: Right.

Slice 4

Cassette B9: Left anterior.
Cassette B10: Left posterior.
Cassette B11: Right posterior.
Cassette B12: Right anterior.

Slice 5

Cassette B13: Left.
Cassette B14: Right.

Slice 6

Cassette B15: Left.

[page 3 of 3]
Cassette B16: Right.
Seminal vesicles
Cassette B17: Left.
Cassette B18: Right.
Bladder resection margin
Cassette B19: Left.
Cassette B20: Right.

Part C is additionally labeled "left pelvic lymph nodes." It consists of multiple irregular fragments of soft-to-firm, yellow-tan to light-brown fibrofatty tissue, measuring 5 x 4 x 1 cm in aggregate. Multiple lymph node candidates are identified. The specimen is entirely submitted as follows:

Cassettes C1-C2: One lymph node candidate, quartered.
Cassettes C3-C4: Two small lymph node candidates each, intact.
Cassettes C5-C6: The entire fibrofatty remnant.

Part D is additionally labeled "right pelvic lymph nodes." It consists of three segments of soft-to-firm, rubbery, yellow-tan fibrofatty tissue, measuring 5.3 x 2 x 1 cm in aggregate. Multiple lymph node candidates are identified. The specimen is entirely submitted as follows:

Cassettes D1-D2: One lymph node candidate each, bisected.
Cassettes D3-D5: Two small lymph node candidates each, submitted intact.
Cassette D6: The entire fibrofatty remnant.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

/Pathology Resident

Electronically signed out on

/Pathologist

Source: NCI Genomic Data Commons file ea1952b2-0e75-4c82-9d87-ff7e4236b958 (TCGA-V1-A8X3.267C0EAB-ECC4-44BC-89C9-8C54F3B22A6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).